Somatic mutation profile of tumor specimen C3L-07625-01 (aliquot CPT0512870006) from CPTAC case C3L-07625, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 72.8 years (26,572 days).
Specimen C3L-07625-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00c4b06c-06e0-4274-b7d1-5eccdce085b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07625-31 (Blood Derived Normal), aliquot CPT0513020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1337b607-81bf-4b87-ae8c-072baa0e1b03

The open-access MAF lists 2,317 somatic variants for this specimen: 1,705 protein-altering or splice-affecting, 527 silent, 85 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,214, Silent 527, Frame Shift Del 324, Frame Shift Ins 87, Nonsense Mutation 47, Intron 44, 3'UTR 15, Splice Region 12, In Frame Del 11, 5'UTR 8, RNA 7, Splice Site 7.

Variants (750 of 2,317; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 52/218 reads (24%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- ATN1 | c.3172C>T p.H1058Y | Missense Mutation (SNP) | VAF 106/505 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as rs1555144358; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BAG3 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 113/591 reads (19%) | catalogued as rs1057517945, CM111933, COSV64842698; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 70/316 reads (22%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BMPR1A | c.176del p.L59* | Frame Shift Del (DEL) | VAF 76/352 reads (22%) | catalogued as rs786201038; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BMPR1A | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 62/265 reads (23%) | catalogued as rs786201040, CM135237, COSV64404915; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.9097del p.T3033Lfs*29 | Frame Shift Del (DEL) | VAF 39/172 reads (23%) | catalogued as rs397507419; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- C19orf12 | c.199del p.A67Lfs*6 (on ENST00000392278 / NM_001031726.3; = p.A56Lfs*6 on NM_031448.6) | Frame Shift Del (DEL) | VAF 54/317 reads (17%) | catalogued as rs398122409, CD129885, CD132613; ClinVar: pathogenic; called by pindel, varscan2
- COL17A1 | c.3676C>T p.R1226* | Nonsense Mutation (SNP) | VAF 108/532 reads (20%) | catalogued as rs121912769, CM950286; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DLD | c.633dup p.V212Sfs*32 | Frame Shift Ins (INS) | VAF 48/186 reads (26%) | catalogued as rs1040811473; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ETFA | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 60/300 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs119458970, CM920245; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.4825dup p.T1609Nfs*4 | Frame Shift Ins (INS) | VAF 81/419 reads (19%) | catalogued as rs397514036; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GDF6 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 148/950 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs387906794, CM100249; ClinVar: pathogenic; called by muse, varscan2
- GLRA1 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 59/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs199547699, CM104312, COSV51010888; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 50/286 reads (17%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 24/144 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PTEN | c.97_99del p.I33del | In Frame Del (DEL) | VAF 31/120 reads (26%) | catalogued as rs1554893765; ClinVar: uncertain significance / likely pathogenic; called by pindel, varscan2
- RRAS2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs782457908, COSV56329532; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 46/228 reads (20%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- SMARCA2 | c.3395G>A p.G1132D | Missense Mutation (SNP) | VAF 78/423 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs387907194, CM1111415, COSV61806947; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/167 reads (18%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- ZBTB42 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 172/691 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730882163, CM1411836; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1601C>T p.P534L (on ENST00000272895 / NM_173076.3; = p.P216L on NM_015657.3) | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.135); catalogued as rs760080854, COSV55955802; called by muse, mutect2, varscan2
- ABCA12 | c.626A>C p.K209T | Missense Mutation (SNP) | VAF 64/253 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV55948568; called by muse, mutect2, varscan2
- ABCA13 | c.13375G>A p.A4459T | Missense Mutation (SNP) | VAF 92/457 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101291264; called by muse, mutect2, varscan2
- ABCA2 | c.2642C>T p.A881V (on ENST00000614293; = p.A851V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/408 reads (21%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.977); catalogued as rs1166365765; called by muse, mutect2, varscan2
- ABCA3 | c.2992del p.R998Afs*11 | Frame Shift Del (DEL) | VAF 174/427 reads (41%) | catalogued as COSV100068720; called by mutect2, pindel, varscan2
- ABCA5 | c.128del p.L43Yfs*4 | Frame Shift Del (DEL) | VAF 8/63 reads (13%) | catalogued as rs751512043; called by mutect2, varscan2
- ABCB10 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 34/520 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540465563, COSV100748097; called by muse, mutect2
- ABCC11 | c.1501G>A p.G501R | Missense Mutation (SNP) | VAF 129/689 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs377008966, COSV62322643; called by muse, mutect2, varscan2
- ABCG5 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 88/626 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs758017120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD17A | c.589G>A p.V197M (on ENST00000292577 / NM_001130111.2; = p.V248M on NM_031213.4) | Missense Mutation (SNP) | VAF 59/900 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1287476745; called by muse, varscan2
- ABHD17C | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 86/543 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1227720263; called by muse, mutect2, varscan2
- ACACB | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 68/334 reads (20%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.011); catalogued as rs373214045; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 37/178 reads (21%) | catalogued as rs757016425; called by mutect2, varscan2
- ACTA1 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 91/518 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as CM095322, COSV64204117; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 85/224 reads (38%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM2 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV55869051; called by muse, mutect2, varscan2
- ADAM30 | c.1846C>T p.R616W | Missense Mutation (SNP) | VAF 90/374 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.786); catalogued as rs374077889; called by muse, varscan2
- ADAM30 | c.1768G>T p.G590C | Missense Mutation (SNP) | VAF 68/380 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65560485; called by muse, varscan2
- ADAMTS13 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 50/957 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.04); catalogued as rs369510827, COSV100747242; called by muse, mutect2
- ADAMTS7 | c.5000C>T p.S1667L | Missense Mutation (SNP) | VAF 131/674 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs749021827; called by muse, mutect2, varscan2
- ADAMTS7 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 162/699 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs749512576, COSV101183000; called by muse, mutect2, varscan2
- ADCY10 | c.4790dup p.N1597Kfs*8 | Frame Shift Ins (INS) | VAF 46/265 reads (17%) | catalogued as rs753500756; called by mutect2, varscan2
- ADCY9 | c.3424G>A p.A1142T | Missense Mutation (SNP) | VAF 96/642 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs770583603, COSV53580685; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 46/209 reads (22%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA1 | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 119/473 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV100811043; called by muse, mutect2, varscan2
- ADGRB1 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 155/1070 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1423141330; called by muse, varscan2
- ADGRG5 | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 51/374 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs200866735; called by muse, mutect2, varscan2
- ADGRG7 | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 66/413 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs772948883, COSV56298453; called by muse, mutect2, varscan2
- ADNP2 | c.2669A>G p.Y890C | Missense Mutation (SNP) | VAF 128/600 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs1196115403; called by muse, mutect2, varscan2
- ADRB2 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 128/581 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs765634337; called by muse, mutect2, varscan2
- AFDN | c.509del p.K170Rfs*53 | Frame Shift Del (DEL) | VAF 49/317 reads (15%) | catalogued as rs1431558072; called by mutect2, pindel, varscan2
- AGO2 | c.2116G>A p.V706M | Missense Mutation (SNP) | VAF 115/622 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs1285375898; called by muse, mutect2, varscan2
- AGPAT5 | c.100del p.V34Sfs*54 | Frame Shift Del (DEL) | VAF 181/752 reads (24%) | catalogued as rs766863549; called by mutect2, pindel, varscan2
- AIFM3 | c.357C>T p.G119= | Splice Region (SNP) | VAF 110/434 reads (25%) | catalogued as rs542222592; called by muse, mutect2, varscan2
- AIRE | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 81/532 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs554954634, COSV52393789; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 26/152 reads (17%) | catalogued as rs778351035; called by mutect2, pindel, varscan2
- AKAP17A | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 217/907 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.312); catalogued as rs762688186, COSV58312105; called by muse, mutect2, varscan2
- AKAP3 | c.1300dup p.M434Nfs*4 | Frame Shift Ins (INS) | VAF 82/362 reads (23%) | catalogued as rs750420000; called by mutect2, pindel, varscan2
- ALG10 | c.904del p.S302Pfs*17 | Frame Shift Del (DEL) | VAF 24/234 reads (10%) | catalogued as rs779782051; called by mutect2, pindel, varscan2
- ALG2 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 87/370 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53059833; called by muse, mutect2, varscan2
- ALPI | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 97/569 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.166); catalogued as rs781092139; called by muse, mutect2, varscan2
- ALPK3 | c.3037C>T p.R1013C | Missense Mutation (SNP) | VAF 52/684 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs142109538; called by muse, mutect2
- ALPK3 | c.3559G>A p.E1187K | Missense Mutation (SNP) | VAF 62/766 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs1419037862; called by muse, mutect2
- AMDHD1 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 147/592 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57140072; called by muse, mutect2, varscan2
- AMIGO3 | c.1228T>C p.C410R | Missense Mutation (SNP) | VAF 194/794 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs778615839, COSV57538874; called by muse, varscan2
- ANAPC4 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 68/287 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1204859333; called by muse, mutect2, varscan2
- ANGPTL7 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 141/607 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs775409689, COSV100816141; called by muse, mutect2, varscan2
- ANK2 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 68/305 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759136608, COSV100001604; called by muse, mutect2, varscan2
- ANK2 | c.4212dup p.A1405Cfs*6 | Frame Shift Ins (INS) | VAF 24/178 reads (13%) | catalogued as rs763282994; called by mutect2, varscan2
- ANKRD13A | c.1037A>G p.D346G | Missense Mutation (SNP) | VAF 77/325 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs886220092; called by muse, mutect2, varscan2
- ANKRD62 | c.1439del p.K480Sfs*5 | Frame Shift Del (DEL) | VAF 28/134 reads (21%) | catalogued as rs774510795; called by mutect2, varscan2
- ANKS1B | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748145482, COSV100248315; called by muse, mutect2, varscan2
- ANKZF1 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 170/723 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as rs544276732, COSV55475763, COSV99850230; called by muse, mutect2, varscan2
- APC2 | c.5427del p.G1810Afs*46 | Frame Shift Del (DEL) | VAF 182/960 reads (19%) | catalogued as rs1294484958; called by mutect2, pindel, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 56/232 reads (24%) | catalogued as rs546686089; called by mutect2, varscan2
- APOB | c.10171A>G p.R3391G | Missense Mutation (SNP) | VAF 76/350 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV51954362; called by muse, mutect2, varscan2
- APOB | c.1884G>T p.M628I | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.527); catalogued as COSV51933893; called by muse, mutect2, varscan2
- APOBEC3B | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 53/976 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV59840279; called by muse, mutect2
- ARFGAP3 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 72/356 reads (20%) | catalogued as rs749122444; called by muse, mutect2, varscan2
- ARHGAP39 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 116/1274 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.332); catalogued as rs369269697; called by muse, mutect2
- ARHGEF10L | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 108/409 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779955786, COSV51429038, COSV51431042; called by muse, mutect2, varscan2
- ARHGEF40 | c.3347C>T p.T1116M | Missense Mutation (SNP) | VAF 113/566 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs754393228, COSV53884270; called by muse, mutect2, varscan2
- ARID1A | c.1015del p.A339Lfs*24 | Frame Shift Del (DEL) | VAF 209/1019 reads (21%) | catalogued as rs1232964733; called by mutect2, pindel, varscan2
- ARID1A | c.4142C>T p.A1381V | Missense Mutation (SNP) | VAF 91/434 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV61370723; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 131/660 reads (20%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ASB11 | c.68dup p.F24Lfs*2 | Frame Shift Ins (INS) | VAF 46/185 reads (25%) | catalogued as rs770804405; called by mutect2, varscan2
- ASIC4 | c.1286G>A p.G429D (on ENST00000347842 / NM_182847.3; = p.G448D on NM_018674.6) | Missense Mutation (SNP) | VAF 111/486 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1443629051; called by muse, mutect2, varscan2
- ATG2A | c.1298del p.G433Vfs*2 | Frame Shift Del (DEL) | VAF 71/767 reads (9%) | catalogued as rs751537436, COSV65967044; called by mutect2, pindel
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 52/253 reads (21%) | catalogued as rs771531141; called by mutect2, varscan2
- ATIC | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 68/299 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs150438200; called by muse, mutect2, varscan2
- ATMIN | c.1713G>T p.Q571H | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV55147832; called by muse, mutect2, varscan2
- ATP1A2 | c.3023G>A p.R1008Q | Missense Mutation (SNP) | VAF 69/358 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs781023681, COSV63402063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP9B | c.2896A>G p.M966V | Missense Mutation (SNP) | VAF 64/328 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs1203125662; called by muse, varscan2
- ATRX | c.5090G>A p.S1697N | Missense Mutation (SNP) | VAF 73/351 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.56); catalogued as COSV64879653; called by muse, mutect2, varscan2
- ATXN2L | c.1673G>T p.S558I | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV57369398; called by muse, mutect2
- AUTS2 | c.2450G>A p.R817H | Missense Mutation (SNP) | VAF 37/602 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs150219264; called by muse, mutect2
- AVPR1A | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs748353963, COSV54547767; called by muse, varscan2
- AVPR2 | c.738dup p.R247Afs*12 | Frame Shift Ins (INS) | VAF 187/947 reads (20%) | catalogued as rs781942628; called by mutect2, pindel, varscan2
- B4GALNT4 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 250/1029 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1214882729; called by muse, mutect2, varscan2
- BARD1 | c.1788del p.K596Nfs*9 | Frame Shift Del (DEL) | VAF 46/220 reads (21%) | catalogued as COSV53612208; called by pindel, varscan2
- BBS12 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs200240034, COSV58561755; called by muse, mutect2, varscan2
- BDH1 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 105/503 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as rs199910914; called by muse, mutect2, varscan2
- BDKRB2 | c.880A>G p.T294A | Missense Mutation (SNP) | VAF 130/619 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs745400008; called by muse, mutect2, varscan2
- BET1L | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 65/268 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as rs749580292, COSV57315175; called by muse, mutect2, varscan2
- BHLHE22 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 103/983 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs920864420; called by muse, mutect2, varscan2
- BICDL2 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 98/417 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs760332221; called by muse, mutect2, varscan2
- BMPR2 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs773416598, COSV101001507; called by muse, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 54/351 reads (15%) | catalogued as rs772920507, COSV65808737; called by pindel, varscan2
- BOC | c.3311G>A p.R1104H | Missense Mutation (SNP) | VAF 90/383 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs749757705, COSV104383253; called by muse, mutect2, varscan2
- BPIFB1 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 89/427 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs570505589, COSV53607435; called by muse, mutect2, varscan2
- BRINP1 | c.145C>A p.H49N | Missense Mutation (SNP) | VAF 84/398 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV56301399; called by muse, mutect2, varscan2
- BSN | c.6220G>A p.G2074S | Missense Mutation (SNP) | VAF 111/642 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs769453767; called by muse, mutect2, varscan2
- BTD | c.1109C>A p.A370D | Missense Mutation (SNP) | VAF 108/483 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.265); catalogued as rs557738433; called by muse, mutect2, varscan2
- C10orf71 | c.3706C>T p.R1236C | Missense Mutation (SNP) | VAF 127/806 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1267177303; called by muse, mutect2, varscan2
- C12orf4 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs532268400, COSV54205508; called by muse, mutect2, varscan2
- C19orf18 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as COSV100071713; called by muse, mutect2, varscan2
- C1QTNF1 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 125/580 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs117861016; called by muse, mutect2, varscan2
- C1orf112 | c.756del p.F252Lfs*51 | Frame Shift Del (DEL) | VAF 63/259 reads (24%) | catalogued as rs1558068270; called by mutect2, pindel, varscan2
- C2CD4D | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 165/769 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1448773517; called by muse, mutect2, varscan2
- C4A | c.2777C>T p.A926V | Missense Mutation (SNP) | VAF 144/864 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as rs762474221, COSV71179157; called by muse, mutect2, varscan2
- C8orf58 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 73/324 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs767732421; called by muse, mutect2, varscan2
- CABLES1 | c.689C>A p.P230H | Missense Mutation (SNP) | VAF 147/658 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV99908961; called by muse, mutect2, varscan2
- CACNA1B | c.6377G>A p.R2126H | Missense Mutation (SNP) | VAF 172/799 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1303415147; called by muse, mutect2, varscan2
- CACNA1C | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 97/438 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs755609118, COSV59738272; called by muse, mutect2, varscan2
- CACNA1I | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 89/451 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1313739182, COSV60804712; called by muse, varscan2
- CACNA2D4 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 97/420 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373696894; called by muse, mutect2, varscan2
- CACNG1 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 49/413 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs921123953, COSV99871780; called by muse, mutect2, varscan2
- CAD | c.2284G>A p.V762I | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as rs761444771; called by muse, mutect2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 57/314 reads (18%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CARD10 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 125/628 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs201397783; called by muse, mutect2, varscan2
- CARF | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs781415395; called by muse, mutect2, varscan2
- CBY2 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 120/531 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.176); catalogued as rs555632513; called by muse, mutect2, varscan2
- CCAR2 | c.1513dup p.L505Pfs*32 | Frame Shift Ins (INS) | VAF 73/520 reads (14%) | catalogued as rs748274275; called by mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 23/200 reads (12%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC8 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 153/691 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.802); catalogued as rs1412008655, COSV56772673; called by muse, mutect2, varscan2
- CCNT1 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 82/365 reads (22%) | catalogued as COSV56064151; called by muse, mutect2, varscan2
- CCT8 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs1432681529, COSV99071701; called by muse, varscan2
- CCT8L2 | c.1654dup p.I552Nfs*6 | Frame Shift Ins (INS) | VAF 36/190 reads (19%) | catalogued as rs780034402; called by mutect2, varscan2
- CCT8L2 | c.1435G>T p.G479C | Missense Mutation (SNP) | VAF 75/444 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1316641813, COSV63463669; called by muse, mutect2, varscan2
- CDC42BPA | c.4933G>A p.A1645T (on ENST00000334218 / NM_001366019.2; = p.A1632T on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/375 reads (24%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.99); catalogued as rs756838979, COSV62013394; called by muse, mutect2, varscan2
- CDH22 | c.964A>G p.S322G | Missense Mutation (SNP) | VAF 156/558 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs774356645, COSV64836824; called by muse, varscan2
- CDH23 | c.4607G>A p.S1536N | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV99822520; called by muse, mutect2, varscan2
- CDH24 | c.1798G>T p.G600W | Missense Mutation (SNP) | VAF 30/787 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1243715863; called by muse, mutect2
- CDK11A | c.2023C>T p.R675C (on ENST00000378633 / NM_001313896.2; = p.R672C on NM_024011.4) | Missense Mutation (SNP) | VAF 98/431 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769472924, COSV99319156; called by muse, mutect2, varscan2
- CELSR1 | c.5544del p.T1849Rfs*8 | Frame Shift Del (DEL) | VAF 86/430 reads (20%) | catalogued as rs776824429; called by mutect2, varscan2
- CELSR3 | c.5083C>T p.R1695W | Missense Mutation (SNP) | VAF 87/563 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867726772; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CENPJ | c.3077G>A p.S1026N | Missense Mutation (SNP) | VAF 87/440 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.148); catalogued as rs1251085590; called by muse, mutect2
- CES5A | c.1387G>A p.G463S | Missense Mutation (SNP) | VAF 40/596 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs771979119; called by muse, mutect2
- CFAP299 | c.448del p.R150Dfs*9 | Frame Shift Del (DEL) | VAF 48/268 reads (18%) | catalogued as rs761800837; called by mutect2, varscan2
- CGAS | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 66/970 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs926274545; called by muse, mutect2
- CGB2 | c.134T>C p.I45T | Missense Mutation (SNP) | VAF 32/527 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.079); catalogued as rs1049493124; called by muse, mutect2, varscan2
- CHD4 | c.5369G>A p.R1790Q (on ENST00000357008 / NM_001363606.2; = p.R1801Q on NM_001273.5) | Missense Mutation (SNP) | VAF 65/408 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs763955970, COSV58896903; called by muse, mutect2, varscan2
- CHD5 | c.5128G>A p.G1710R | Missense Mutation (SNP) | VAF 81/370 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769117837; called by muse, varscan2
- CHD5 | c.2555T>G p.L852R | Missense Mutation (SNP) | VAF 116/536 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52422428; called by muse, mutect2
- CHD7 | c.5114C>T p.P1705L | Missense Mutation (SNP) | VAF 136/821 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs373986410; called by muse, mutect2, varscan2
- CHD9 | c.4888C>T p.R1630C | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1204735412; called by muse, mutect2, varscan2
- CHEK2 | c.1690C>T p.R564W (on ENST00000382580 / NM_001005735.2; = p.R521W on NM_007194.4) | Missense Mutation (SNP) | VAF 90/433 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs533475838, COSV60426133; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHMP1A | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 123/578 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as rs748373933, COSV53684137; called by muse, mutect2, varscan2
- CHST1 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 146/648 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.035); catalogued as rs1268747124, COSV100346214; called by muse, mutect2, varscan2
- CHST15 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 100/490 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60562073; called by muse, mutect2, varscan2
- CIBAR2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 126/595 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101608281; called by muse, mutect2, varscan2
- CIC | c.3743del p.P1248Hfs*54 | Frame Shift Del (DEL) | VAF 183/900 reads (20%) | catalogued as COSV50671496; called by mutect2, pindel, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 52/126 reads (41%) | catalogued as rs369752219; called by mutect2, varscan2
- CLSTN1 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 25/522 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1363487449; called by muse, mutect2
- CNKSR2 | c.2370G>T p.E790D | Missense Mutation (SNP) | VAF 60/790 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV54266395; called by muse, mutect2
- CNNM4 | c.1312del p.L438Sfs*41 | Frame Shift Del (DEL) | VAF 90/430 reads (21%) | catalogued as rs746879923; called by mutect2, pindel, varscan2
- CNTRL | c.5399A>G p.E1800G | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs764744947; called by muse, mutect2, varscan2
- COL16A1 | c.3946C>T p.R1316* | Nonsense Mutation (SNP) | VAF 82/493 reads (17%) | catalogued as rs1250799621; called by muse, mutect2, varscan2
- COL22A1 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 93/566 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs759719626; called by muse, mutect2, varscan2
- COL27A1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 136/709 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.041); catalogued as rs748184039; called by muse, mutect2, varscan2
- COLEC11 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 130/562 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as rs1204455089; called by muse, mutect2, varscan2
- CORIN | c.2747C>T p.P916L | Missense Mutation (SNP) | VAF 104/483 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs760929855; called by muse, mutect2, varscan2
- CPSF1 | c.3868_3869del p.S1290Ffs*31 | Frame Shift Del (DEL) | VAF 110/820 reads (13%) | catalogued as rs1554862551; called by pindel, varscan2
- CPT1A | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 101/659 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs878856345, COSV55757242, COSV99681469; called by muse, mutect2, varscan2
- CRACD | c.3391G>A p.V1131M | Missense Mutation (SNP) | VAF 95/404 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as rs571781158, COSV51718526; called by muse, mutect2, varscan2
- CROCC | c.5929C>T p.R1977W | Missense Mutation (SNP) | VAF 52/896 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.106); catalogued as rs1460097232, COSV100977603; called by muse, mutect2
- CRYBG3 | c.5306del p.N1769Mfs*14 | Frame Shift Del (DEL) | VAF 56/313 reads (18%) | catalogued as rs1417190140; called by mutect2, pindel, varscan2
- CSF2 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 110/485 reads (23%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.759); catalogued as rs1161863330, COSV51522338; called by muse, mutect2, varscan2
- CSK | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 96/436 reads (22%) | catalogued as COSV99583999; called by muse, mutect2, varscan2
- CSMD3 | c.4886C>T p.A1629V (on ENST00000297405 / NM_001363185.1; = p.A1525V on NM_052900.3) | Missense Mutation (SNP) | VAF 36/353 reads (10%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.611); catalogued as rs778050124, COSV52159807; called by muse, mutect2
- CSMD3 | c.28C>T p.R10* | Nonsense Mutation (SNP) | VAF 90/621 reads (14%) | catalogued as rs779460744, COSV52105745, COSV99830721; called by muse, mutect2, varscan2
- CSNK2A2 | c.610C>T p.L204F | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52641962; called by muse, mutect2, varscan2
- CSNKA2IP | c.836A>G p.Q279R | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.011); catalogued as COSV50712227; called by muse, mutect2, varscan2
- CSPG4 | c.1471C>T p.R491* | Nonsense Mutation (SNP) | VAF 106/526 reads (20%) | catalogued as rs757011081, COSV57895646; called by muse, varscan2
- CST7 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 84/352 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.27); catalogued as rs770020061, COSV54176280; called by muse, mutect2, varscan2
- CTCF | c.2070del p.E691Sfs*30 | Frame Shift Del (DEL) | VAF 105/529 reads (20%) | catalogued as rs1400980130; called by mutect2, pindel, varscan2
- CTIF | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 98/492 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs139514005; called by muse, varscan2
- CUL2 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 51/242 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373965981; called by muse, mutect2, varscan2
- CXADR | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as rs778453029, COSV53030419; called by muse, mutect2, varscan2
- CYB5R2 | c.433del p.T145Hfs*8 | Frame Shift Del (DEL) | VAF 99/456 reads (22%) | catalogued as rs775988957; called by mutect2, pindel, varscan2
- CYP11B2 | c.39del p.W15Gfs*36 | Frame Shift Del (DEL) | VAF 84/872 reads (10%) | catalogued as COSV59995034; called by mutect2, pindel, varscan2
- CYP2D6 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 117/590 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764892620; called by muse, mutect2, varscan2
- CYP39A1 | c.270dup p.V91Sfs*4 | Frame Shift Ins (INS) | VAF 30/203 reads (15%) | catalogued as rs1225765844; called by mutect2, pindel, varscan2
- DACT3 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 118/565 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV56260962; called by muse, mutect2, varscan2
- DCAF12L1 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 136/861 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV64422152; called by muse, mutect2, varscan2
- DCAF12L1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 173/762 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as rs1321847100; called by muse, mutect2, varscan2
- DCAF4L2 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 80/600 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1388562595, COSV60476670; called by muse, mutect2, varscan2
- DCHS1 | c.9428T>C p.V3143A | Missense Mutation (SNP) | VAF 31/763 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as rs1344347397; called by muse, mutect2
- DDX21 | c.380C>A p.A127D | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.082); catalogued as COSV62556869; called by muse, mutect2, varscan2
- DENND1A | c.1508A>G p.H503R | Missense Mutation (SNP) | VAF 112/426 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1325890584; called by muse, mutect2, varscan2
- DENND3 | c.923T>C p.V308A | Missense Mutation (SNP) | VAF 64/658 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs1368369994; called by muse, mutect2
- DEPDC1 | c.1064dup p.N355Kfs*9 | Frame Shift Ins (INS) | VAF 41/235 reads (17%) | catalogued as rs760464782; called by mutect2, varscan2
- DEPTOR | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 76/513 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs375154981; called by muse, mutect2, varscan2
- DGKQ | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 73/495 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs764189185, COSV56618290; called by muse, mutect2, varscan2
- DGKZ | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 28/1006 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1482253726; called by muse, mutect2
- DHRS1 | c.343A>G p.M115V | Missense Mutation (SNP) | VAF 77/452 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99852283; called by muse, mutect2, varscan2
- DIRAS3 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 29/583 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1229728446, COSV63970650; called by muse, mutect2
- DISP2 | c.4096C>T p.R1366* | Nonsense Mutation (SNP) | VAF 146/705 reads (21%) | catalogued as rs780263622, COSV99139818; called by muse, mutect2, varscan2
- DLGAP3 | c.2280del p.A761Pfs*15 | Frame Shift Del (DEL) | VAF 73/534 reads (14%) | catalogued as COSV99333117; called by mutect2, pindel, varscan2
- DLGAP4 | c.2134C>T p.R712W (on ENST00000339266 / NM_001365621.1; = p.R709W on NM_014902.6) | Missense Mutation (SNP) | VAF 18/406 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1487528852, COSV100211630; called by muse, mutect2
- DLL4 | c.1594G>A p.V532I | Missense Mutation (SNP) | VAF 75/622 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs777516760, COSV51061906; called by muse, mutect2, varscan2
- DMRTA1 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 173/780 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361906032; called by muse, mutect2, varscan2
- DNAH11 | c.7030G>A p.A2344T | Missense Mutation (SNP) | VAF 65/353 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV60938090; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 27/122 reads (22%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAJB13 | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 65/344 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60271212; called by muse, mutect2, varscan2
- DNAJB5 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 57/505 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV56624619; called by muse, mutect2, varscan2
- DNAJB8 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 148/662 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as rs746861310; called by muse, mutect2, varscan2
- DNALI1 | c.757_759del p.K253del (on ENST00000296218; = p.K231del on NM_003462.5) | In Frame Del (DEL) | VAF 104/514 reads (20%) | catalogued as rs757201027; called by pindel, varscan2
- DNMT1 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 113/572 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1003447106, COSV100532505, COSV100532901; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK1 | c.4057C>T p.R1353W | Missense Mutation (SNP) | VAF 18/361 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1293651177, COSV54763963; called by muse, mutect2
- DOCK5 | c.1735dup p.M579Nfs*5 | Frame Shift Ins (INS) | VAF 49/189 reads (26%) | catalogued as rs1282784562; called by mutect2, varscan2
- DOP1A | c.3053G>A p.R1018H | Missense Mutation (SNP) | VAF 42/341 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs777537189, COSV52708013, COSV52708094; called by muse, mutect2, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 73/294 reads (25%) | catalogued as rs35482889; called by mutect2, varscan2
- DPT | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 87/578 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs749307060; called by muse, mutect2, varscan2
- DRP2 | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 156/811 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs766073418, COSV101235182; called by muse, mutect2, varscan2
- DUSP9 | c.53del p.P18Rfs*25 | Frame Shift Del (DEL) | VAF 161/770 reads (21%) | catalogued as rs1557035731; called by mutect2, pindel, varscan2
- DUXA | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 56/216 reads (26%) | catalogued as rs773479524, COSV101617164, COSV73729528; called by muse, mutect2, varscan2
- DYNC1H1 | c.6871G>A p.V2291M | Missense Mutation (SNP) | VAF 61/381 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779194599; called by muse, mutect2, varscan2
- DYNC2H1 | c.5176C>T p.R1726* | Nonsense Mutation (SNP) | VAF 25/340 reads (7%) | catalogued as rs772321133, CM130524, COSV100518383; called by muse, mutect2
- EBF1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs766532365, COSV58173698, COSV58178759; called by muse, mutect2
- EBF2 | c.1348A>G p.I450V | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs1411689272; called by muse, varscan2
- EDNRB | c.301G>A p.A101T (on ENST00000377211 / NM_001201397.1; = p.A11T on NM_000115.5) | Missense Mutation (SNP) | VAF 135/686 reads (20%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.187); catalogued as COSV57521359; called by muse, mutect2, varscan2
- EED | c.521T>C p.I174T | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs1369539791; called by muse, mutect2, varscan2
- EFCAB1 | c.78C>G p.N26K | Missense Mutation (SNP) | VAF 16/476 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100030974; called by muse, mutect2
- EHBP1L1 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 102/509 reads (20%) | catalogued as rs780383774, COSV58573815; called by muse, mutect2, varscan2
- EHMT1 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 78/352 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs369565794; called by muse, varscan2
- ELOA2 | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 72/358 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); catalogued as rs202109165; called by muse, varscan2
- EME2 | c.41_46del p.Q14_G15del | In Frame Del (DEL) | VAF 201/536 reads (38%) | catalogued as rs989061245; called by mutect2, pindel, varscan2
- ENC1 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 146/559 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs780317395, COSV56630184; called by muse, mutect2, varscan2
- ENO3 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 59/326 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.076); catalogued as rs570595152; called by muse, mutect2, varscan2
- EPB41 | c.1850A>G p.E617G (on ENST00000343067 / NM_001166005.2; = p.E408G on NM_203342.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV58050589; called by muse, mutect2, varscan2
- EPB41L5 | c.1489G>A p.V497I | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99758174; called by muse, mutect2, varscan2
- EPHB2 | c.2365C>A p.P789T (on ENST00000400191 / NM_001309193.2; = p.P790T on NM_004442.7) | Missense Mutation (SNP) | VAF 19/380 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65863099; called by muse, mutect2
- EPN1 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 68/725 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99321413; called by muse, mutect2
- EPN1 | c.833del p.G278Afs*164 (on ENST00000270460 / NM_001321263.1; = p.G253Afs*163 on NM_013333.3) | Frame Shift Del (DEL) | VAF 187/820 reads (23%) | catalogued as rs755604942; called by mutect2, pindel, varscan2
- ERN2 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 61/398 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.325); catalogued as COSV55620985; called by muse, mutect2, varscan2
- EVC2 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 117/560 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV99381049; called by muse, mutect2, varscan2
- EVI2B | c.593del p.N198Tfs*6 | Frame Shift Del (DEL) | VAF 64/285 reads (22%) | catalogued as rs765136869; called by mutect2, pindel, varscan2
- EZHIP | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 142/648 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.011); catalogued as rs782300283; called by muse, mutect2, varscan2
- F13A1 | c.1201del p.Q401Rfs*64 | Frame Shift Del (DEL) | VAF 52/313 reads (17%) | catalogued as rs1290008988, CM960522; called by mutect2, pindel, varscan2
- FAF2 | c.282G>T p.W94C | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as rs1421057704; called by muse, mutect2, varscan2
- FAM151A | c.351del p.T118Lfs*43 | Frame Shift Del (DEL) | VAF 90/593 reads (15%) | catalogued as rs749953492; called by mutect2, pindel, varscan2
- FAM181A | c.742A>G p.M248V | Missense Mutation (SNP) | VAF 44/704 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs775767652; called by muse, mutect2
- FAM184A | c.2855G>T p.R952L | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58859418; called by muse, mutect2, varscan2
- FAM217B | c.605A>C p.K202T | Missense Mutation (SNP) | VAF 108/526 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs879232032; called by muse, mutect2, varscan2
- FAM25C | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 108/576 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as rs80266306; called by muse, mutect2, varscan2
- FAM3B | c.582del p.G195Afs*32 | Frame Shift Del (DEL) | VAF 65/388 reads (17%) | catalogued as rs764092218; called by mutect2, pindel, varscan2
- FAM47A | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 158/771 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs753875155, COSV60498289, COSV60499246; called by muse, mutect2, varscan2
- FAM50B | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 135/621 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1288238703, COSV66654673; called by muse, mutect2, varscan2
- FAM83B | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 71/351 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1405407415, COSV60920130; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 48/178 reads (27%) | catalogued as rs748967872; called by mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 23/166 reads (14%) | catalogued as rs746983128; called by mutect2, varscan2
- FBN3 | c.1803del p.L602Wfs*3 | Frame Shift Del (DEL) | VAF 157/698 reads (22%) | catalogued as rs772353703; called by mutect2, varscan2
- FBXL12 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 41/697 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs138149906; called by muse, mutect2
- FER1L5 | c.4649G>A p.R1550Q (on ENST00000623019; = p.R1523Q on NM_001293083.2) | Missense Mutation (SNP) | VAF 50/600 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.692); catalogued as rs745681758, COSV67606278; called by muse, mutect2
- FER1L6 | c.2546C>A p.P849H | Missense Mutation (SNP) | VAF 78/510 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101205212; called by muse, mutect2, varscan2
- FER1L6 | c.5252G>A p.R1751H | Missense Mutation (SNP) | VAF 77/480 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764812791, COSV67548995; called by muse, mutect2, varscan2
- FGFR3 | c.381C>T p.D127= | Splice Region (SNP) | VAF 95/528 reads (18%) | catalogued as rs762778478, COSV53410160; ClinVar: likely benign; called by muse, mutect2, varscan2
- FGFR4 | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 112/404 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV52803533; called by muse, mutect2, varscan2
- FMN1 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 55/476 reads (12%) | SIFT tolerated, low confidence (0.43); catalogued as rs745819682; called by muse, mutect2, varscan2
- FNTA | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs368301964; called by muse, mutect2, varscan2
- FOXA3 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 184/733 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs1428674521; called by muse, mutect2, varscan2
- FOXD4L3 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 59/603 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as rs1370605695; called by muse, mutect2, varscan2
- FOXE3 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs996278928; called by muse, varscan2
- FOXK2 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 64/424 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1443122666; called by muse, mutect2, varscan2
- FOXO1 | c.281T>C p.V94A | Missense Mutation (SNP) | VAF 72/510 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1482440466; called by muse, mutect2, varscan2
- FOXO3 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 39/718 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs1214868548; called by muse, mutect2
- FRMD1 | c.635A>G p.Y212C | Missense Mutation (SNP) | VAF 111/433 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1378667289; called by muse, mutect2, varscan2
- FRS3 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 131/555 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs113605542; called by muse, mutect2, varscan2
- FRYL | c.783A>G p.I261M | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51964268; called by muse, mutect2, varscan2
- FSD1L | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 46/253 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.196); catalogued as rs201446130, COSV65997294; called by muse, mutect2, varscan2
- FTCD | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 122/786 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs757496597, COSV52426415; called by muse, mutect2, varscan2
- FUT1 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 41/762 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs753966600, COSV59569394; called by muse, mutect2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 97/248 reads (39%) | catalogued as rs756304971; called by mutect2, varscan2
- FZD6 | c.1521del p.F507Lfs*25 | Frame Shift Del (DEL) | VAF 49/443 reads (11%) | catalogued as COSV62470622; called by mutect2, pindel, varscan2
- FZD6 | c.1939C>T p.R647W | Missense Mutation (SNP) | VAF 72/460 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.394); catalogued as rs201432167, COSV62470682; called by muse, mutect2, varscan2
- GABRG3 | c.1346del p.F449Sfs*25 | Frame Shift Del (DEL) | VAF 78/330 reads (24%) | catalogued as COSV61524300; called by mutect2, varscan2
- GAPDH | c.586_587del p.W196Afs*2 | Frame Shift Del (DEL) | VAF 80/419 reads (19%) | catalogued as rs778058544; called by pindel, varscan2
- GAS2L3 | c.1951A>C p.T651P | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57158113; called by muse, mutect2
- GBP6 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs116036340; called by muse, mutect2, varscan2
- GDAP1 | c.416G>A p.G139D | Missense Mutation (SNP) | VAF 59/550 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55187383; called by muse, mutect2, varscan2
- GFRA3 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 96/525 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); catalogued as rs368999264; called by muse, mutect2, varscan2
- GFUS | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 37/802 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99643226; called by muse, mutect2
- GHDC | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 112/734 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as rs369536051; called by muse, mutect2, varscan2
- GLDC | c.2137G>A p.V713M | Missense Mutation (SNP) | VAF 58/449 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as rs912659426; ClinVar: uncertain significance; called by muse, varscan2
- GLI2 | c.2600C>T p.A867V (on ENST00000361492 / NM_001374353.1; = p.A884V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 204/880 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs1485605591; called by muse, mutect2, varscan2
- GLIS3 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 152/710 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as rs773807925; called by muse, mutect2, varscan2
- GOLGA4 | c.2864del p.K955Rfs*16 | Frame Shift Del (DEL) | VAF 56/214 reads (26%) | catalogued as rs754602522; called by mutect2, varscan2
- GOLGA6L10 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 108/883 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.502); catalogued as rs764904801; called by muse, varscan2
- GOLGA8G | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1314445983; called by mutect2, varscan2
- GPATCH2 | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 53/339 reads (16%) | catalogued as rs772198086, COSV65134606; called by muse, mutect2, varscan2
- GPD1 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 103/415 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.755); catalogued as rs376155208; called by muse, mutect2, varscan2
- GPR119 | c.893A>G p.K298R | Missense Mutation (SNP) | VAF 131/695 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); catalogued as COSV99358509; called by muse, mutect2, varscan2
- GPR141 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 46/578 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.302); catalogued as rs566037940, COSV57733549; called by muse, mutect2
- GPR148 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 171/744 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs113110453, COSV59308130; called by muse, mutect2, varscan2
- GPR179 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 54/854 reads (6%) | catalogued as rs767509745; called by muse, mutect2
- GPR62 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 212/940 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs1472530619; called by muse, mutect2, varscan2
- GPR83 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 40/886 reads (5%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.009); catalogued as COSV54717394; called by muse, mutect2
- GPR88 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 83/587 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as rs781204817; called by muse, mutect2, varscan2
- GPSM2 | c.1357A>G p.K453E | Missense Mutation (SNP) | VAF 64/321 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV51442513; called by muse, mutect2, varscan2
- GRB7 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 148/594 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1204712650; called by muse, mutect2, varscan2
- GREB1 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 112/606 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768703791, COSV99302004; called by muse, mutect2
- GRK5 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763588844, COSV64865575; called by muse, mutect2, varscan2
- GRK6 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 26/552 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1479264805; called by muse, mutect2
- GSTM5 | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 28/471 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV56656756; called by muse, mutect2
- GSTM5 | c.111C>T p.D37= | Splice Region (SNP) | VAF 81/407 reads (20%) | catalogued as rs1276733007, COSV99859808; called by muse, mutect2, varscan2
- GTSE1 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 113/694 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1245767809, COSV101483230; called by muse, varscan2
- GUCY2D | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 241/956 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.392); catalogued as rs776276813; called by muse, mutect2, varscan2
- HARBI1 | c.49C>A p.R17S | Missense Mutation (SNP) | VAF 39/468 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); catalogued as rs753077232; called by muse, mutect2
- HAS1 | c.884G>A p.C295Y | Missense Mutation (SNP) | VAF 76/418 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55789662; called by muse, varscan2
- HCRTR2 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 93/365 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs755365044, COSV63793832; called by muse, mutect2, varscan2
- HECTD4 | c.11180del p.K3727Rfs*11 | Frame Shift Del (DEL) | VAF 110/469 reads (23%) | catalogued as rs761294926; called by mutect2, varscan2
- HHIPL1 | c.2320G>A p.V774M | Missense Mutation (SNP) | VAF 167/620 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.787); catalogued as rs907508717; called by muse, mutect2, varscan2
- HIC2 | c.1700G>A p.G567D | Missense Mutation (SNP) | VAF 134/656 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV68042831; called by muse, mutect2, varscan2
- HIPK4 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 132/602 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs775166307, COSV52520863; called by muse, mutect2, varscan2
- HLA-B | c.19del p.R7Efs*13 | Frame Shift Del (DEL) | VAF 114/350 reads (33%) | catalogued as COSV69520663, COSV69521156; called by pindel, varscan2
- HNF4A | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 105/487 reads (22%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs374856505; called by muse, mutect2, varscan2
- HOXA3 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 127/586 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV100415241; called by muse, mutect2, varscan2
- HOXB4 | c.353del p.P118Rfs*33 | Frame Shift Del (DEL) | VAF 108/706 reads (15%) | catalogued as rs1323181055, COSV60178862; called by mutect2, pindel, varscan2
- HOXD1 | c.746A>G p.H249R | Missense Mutation (SNP) | VAF 102/485 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1435053452; called by muse, mutect2, varscan2
- HPS1 | c.1273G>A p.V425M | Missense Mutation (SNP) | VAF 135/614 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as rs1157200206, COSV100282738; called by muse, mutect2, varscan2
- HRC | c.990G>T p.E330D | Missense Mutation (SNP) | VAF 129/592 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.891); catalogued as rs1374583067; called by muse, mutect2, varscan2
- HS6ST2 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 187/924 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs755488586, COSV63719211; called by muse, mutect2, varscan2
- HSPA1L | c.1284G>T p.Q428H | Missense Mutation (SNP) | VAF 173/736 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100989397; called by muse, mutect2, varscan2
- HTR3B | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 75/388 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs140308093; called by muse, mutect2, varscan2
- HTR5A | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 91/623 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.404); catalogued as rs148427087; called by muse, mutect2, varscan2
- HYAL3 | c.1031C>A p.P344H | Missense Mutation (SNP) | VAF 134/576 reads (23%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.997); catalogued as COSV100269622; called by mutect2, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 142/626 reads (23%) | catalogued as rs750779916, COSV60737300; called by mutect2, pindel, varscan2
- IFNL1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 54/674 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs771064748; called by muse, mutect2
- IGF2BP1 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 88/386 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as rs769647368; called by muse, mutect2, varscan2
- IGHV3-48 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 96/387 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.483); catalogued as rs375311726; called by muse, mutect2, varscan2
- IGLON5 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 109/492 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99570635; called by muse, mutect2, varscan2
- IGSF8 | c.821A>C p.E274A | Missense Mutation (SNP) | VAF 145/581 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV58758317; called by muse, mutect2, varscan2
- IK | c.1258T>C p.W420R | Missense Mutation (SNP) | VAF 72/354 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.056); catalogued as rs199572934, COSV100845612; called by muse, mutect2, varscan2
- IL17RD | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 62/307 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs771843212; called by muse, mutect2, varscan2
- INCENP | c.1780G>A p.E594K (on ENST00000394818 / NM_001040694.2; = p.E590K on NM_020238.3) | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1363372627, COSV53914060; called by muse, mutect2
- INO80D | c.1969C>T p.R657W | Missense Mutation (SNP) | VAF 92/397 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1465890468; called by muse, mutect2, varscan2
- IPO8 | c.1069dup p.S357Ffs*6 | Frame Shift Ins (INS) | VAF 30/197 reads (15%) | catalogued as rs1438426784; called by mutect2, pindel, varscan2
- IQGAP1 | c.3736G>A p.A1246T | Missense Mutation (SNP) | VAF 71/301 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as rs778634830; called by muse, mutect2, varscan2
- IRX1 | c.1409C>T p.T470M | Missense Mutation (SNP) | VAF 38/374 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs369886565, COSV57358201; called by muse, varscan2
- ISM1 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 143/606 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV52602503, COSV52608802; called by muse, mutect2, varscan2
- ITGAE | c.1801del p.L601Wfs*82 | Frame Shift Del (DEL) | VAF 119/596 reads (20%) | catalogued as rs867709180; called by mutect2, pindel, varscan2
- ITGAV | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs201930300; called by muse, mutect2, varscan2
- ITPR2 | c.5275A>G p.I1759V | Missense Mutation (SNP) | VAF 69/289 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs1403572049; called by muse, mutect2, varscan2
- ITPR2 | c.2365C>T p.R789W | Missense Mutation (SNP) | VAF 96/563 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67274304; called by muse, mutect2, varscan2
- JAG2 | c.3356C>T p.P1119L | Missense Mutation (SNP) | VAF 106/644 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as rs772753236; called by muse, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 114/502 reads (23%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- JAKMIP3 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 44/652 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs574033707, COSV100058593; called by muse, mutect2
- KANSL2 | c.619T>C p.Y207H | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV63480671; called by muse, mutect2
- KAT7 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs1319120269; called by muse, mutect2, varscan2
- KATNBL1 | c.433del p.S145Lfs*19 | Frame Shift Del (DEL) | VAF 42/195 reads (22%) | catalogued as rs1206265094; called by mutect2, pindel, varscan2
- KCNC1 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 60/844 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV56396516; called by muse, mutect2
- KCNG2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.069); catalogued as rs1167871334; called by muse, mutect2
- KCNH6 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 156/676 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs752536722, COSV59002852; called by muse, mutect2, varscan2
- KCNJ10 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 110/579 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1345522131; called by muse, mutect2, varscan2
- KCNJ10 | c.305del p.P102Rfs*96 | Frame Shift Del (DEL) | VAF 144/641 reads (22%) | catalogued as rs765409185; called by mutect2, pindel, varscan2
- KCNQ2 | c.1393C>T p.R465W (on ENST00000359125 / NM_172107.4; = p.R437W on NM_004518.6) | Missense Mutation (SNP) | VAF 198/859 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs756622558; called by muse, mutect2, varscan2
- KCP | c.3015del p.S1006Afs*19 (on ENST00000620378; = p.S1066Afs*19 on NM_001366122.1) | Frame Shift Del (DEL) | VAF 99/696 reads (14%) | catalogued as rs374429628; called by mutect2, pindel, varscan2
- KIAA2012 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.215); catalogued as rs1321998239; called by muse, mutect2
- KIAA2026 | c.2187del p.A730Qfs*26 | Frame Shift Del (DEL) | VAF 34/193 reads (18%) | catalogued as rs749990720; called by mutect2, varscan2
- KIF13B | c.3863del p.K1288Rfs*13 | Frame Shift Del (DEL) | VAF 50/253 reads (20%) | catalogued as rs1287634008; called by mutect2, pindel, varscan2
- KIF14 | c.3759dup p.G1254Wfs*5 | Frame Shift Ins (INS) | VAF 55/198 reads (28%) | catalogued as rs1217383542; called by mutect2, varscan2
- KIF1A | c.3174G>T p.E1058D | Missense Mutation (SNP) | VAF 85/333 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV57482744; called by muse, mutect2, varscan2
- KISS1R | c.43dup p.A15Gfs*179 | Frame Shift Ins (INS) | VAF 112/749 reads (15%) | catalogued as rs1226311997; called by mutect2, pindel, varscan2
- KLF10 | c.1076C>A p.P359H | Missense Mutation (SNP) | VAF 41/807 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs771793433, COSV53436955; called by muse, mutect2
- KLHDC2 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 56/296 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1426623593, COSV100026957; called by muse, mutect2, varscan2
- KLHL25 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 175/721 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as rs368156822; called by muse, mutect2, varscan2
- KLHL36 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 102/507 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.72); catalogued as rs943865876; called by muse, mutect2, varscan2
- KLKB1 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 50/294 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199806113; called by muse, mutect2, varscan2
- KMT2C | c.13651G>T p.G4551C | Missense Mutation (SNP) | VAF 114/535 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51461929; called by muse, mutect2, varscan2
- KRT6C | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 85/604 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs200653200; called by muse, mutect2, varscan2
- KRT72 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 42/653 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs536724669, COSV53374002; called by muse, mutect2
- KRT81 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 86/526 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs747678355; called by muse, varscan2
- KRTAP4-3 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 93/535 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs751921358, COSV66940684; called by muse, varscan2
- L1CAM | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 152/714 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.38); catalogued as rs139197516, COSV100648976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- L1TD1 | c.2168A>G p.E723G | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1263861164; called by muse, mutect2, varscan2
- LAMA3 | c.2645C>T p.A882V | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs1171682252; called by muse, mutect2
- LCN1 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 51/344 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200530565, COSV55017503; called by muse, varscan2
- LETM1 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 134/606 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as rs141640126; called by muse, varscan2
- LHFPL5 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.537); catalogued as rs1353299622; called by muse, varscan2
- LIG1 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 68/340 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.306); catalogued as rs757743358, COSV54389966; called by muse, varscan2
- LIMCH1 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 73/327 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs201461213, COSV58280687; called by muse, mutect2, varscan2
- LMTK3 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 163/709 reads (23%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1396536375; called by muse, mutect2, varscan2
- LOXHD1 | c.6071C>T p.T2024M (on ENST00000642948; = p.T1962M on NM_144612.7) | Missense Mutation (SNP) | VAF 91/370 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369043488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRCH2 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 143/657 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs1431509504, COSV57754567; called by muse, mutect2, varscan2
- LRP12 | c.89C>G p.A30G | Missense Mutation (SNP) | VAF 31/277 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.092); catalogued as COSV99408496; called by muse, mutect2, varscan2
- LRRC3B | c.601del p.T201Lfs*17 | Frame Shift Del (DEL) | VAF 81/417 reads (19%) | catalogued as COSV67521526; called by mutect2, pindel, varscan2
- LRRIQ1 | c.982dup p.I328Nfs*38 | Frame Shift Ins (INS) | VAF 40/188 reads (21%) | catalogued as rs1458169230; called by mutect2, pindel, varscan2
- LRRK1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 38/510 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.572); catalogued as rs773830700, COSV52626458; called by muse, mutect2
- LRRK1 | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 92/441 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs749390141, COSV52617509; called by muse, mutect2, varscan2
- LSM14B | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 175/685 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs1335827345; called by muse, mutect2, varscan2
- LSS | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 106/445 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1316284704, COSV62700331; called by muse, varscan2
- LY6G6C | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 148/691 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs773018610, COSV65404116; called by muse, mutect2, varscan2
- LYSMD4 | c.812C>A p.A271D (on ENST00000409796 / NM_001284417.2; = p.A272D on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/562 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.494); catalogued as rs939619529, COSV60385920; called by muse, mutect2
- LYST | c.8623C>T p.R2875C | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs757503541; called by muse, mutect2, varscan2
- MACF1 | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 64/357 reads (18%) | catalogued as rs1296921678; called by muse, mutect2, varscan2
- MACF1 | c.20402C>T p.A6801V (on ENST00000372915; = p.A4846V on NM_012090.5) | Missense Mutation (SNP) | VAF 26/306 reads (8%) | catalogued as rs1263152705, COSV57112397; called by muse, mutect2
- MACROD2 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs779540577; called by muse, mutect2, varscan2
- MAGEB4 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 19/411 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1470097855, COSV64396948, COSV64397555; called by muse, mutect2
- MAN2B1 | c.1517C>T p.T506M | Missense Mutation (SNP) | VAF 72/449 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as rs139255957, COSV99667268; called by muse, mutect2, varscan2
- MAP1S | c.2918C>T p.A973V | Missense Mutation (SNP) | VAF 225/820 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs769345166; called by muse, mutect2, varscan2
- MAP3K12 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 83/491 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.791); catalogued as rs756119382; called by muse, mutect2, varscan2
- MAP3K14 | c.794A>G p.H265R | Missense Mutation (SNP) | VAF 141/682 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV60924182; called by muse, mutect2, varscan2
- MAP7D3 | c.252C>T p.D84= | Splice Region (SNP) | VAF 55/247 reads (22%) | catalogued as rs771234960, COSV100286517; called by muse, varscan2
- MAPK4 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 198/821 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.616); catalogued as rs774597846; called by muse, mutect2, varscan2
- MAST4 | c.4733C>T p.P1578L (on ENST00000403625 / NM_001164664.2; = p.P1389L on NM_015183.3) | Missense Mutation (SNP) | VAF 22/545 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as rs979897084; called by muse, mutect2
- MATN3 | c.1159del p.T387Hfs*10 | Frame Shift Del (DEL) | VAF 46/220 reads (21%) | catalogued as rs1203662025; called by mutect2, pindel, varscan2
- MCM3AP | c.4207G>A p.A1403T | Missense Mutation (SNP) | VAF 90/410 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1422532590; called by muse, varscan2
- MCM3AP | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1418749023, COSV52442951; called by muse, mutect2
- MCM6 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 71/411 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV51468821; called by muse, mutect2, varscan2
- MCOLN1 | c.1084del p.D362Mfs*10 | Frame Shift Del (DEL) | VAF 121/590 reads (21%) | catalogued as CM003598; called by mutect2, pindel, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 38/202 reads (19%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MDH2 | c.1007C>T p.T336I | Missense Mutation (SNP) | VAF 53/325 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs1554587913; called by muse, mutect2, varscan2
- MED6 | c.121del p.Y41Mfs*15 | Frame Shift Del (DEL) | VAF 41/207 reads (20%) | catalogued as COSV99832909; called by mutect2, pindel, varscan2
- MEGF6 | c.1760del p.P587Rfs*124 | Frame Shift Del (DEL) | VAF 105/489 reads (21%) | catalogued as rs760635494; called by mutect2, pindel, varscan2
- MEP1B | c.967del p.A323Pfs*33 | Frame Shift Del (DEL) | VAF 82/367 reads (22%) | catalogued as rs1295853233, COSV99329190; called by mutect2, pindel, varscan2
- METRN | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 204/726 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs774106811; called by muse, varscan2
- METTL25 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763803362, COSV50259150; called by muse, mutect2, varscan2
- METTL25 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs377321617; called by muse, mutect2, varscan2
- MFSD6 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 85/393 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.054); catalogued as rs754900197; called by muse, mutect2, varscan2
- MIB1 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55088269; called by muse, varscan2
- MICAL3 | c.5933G>A p.R1978Q | Missense Mutation (SNP) | VAF 83/630 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1310318302, COSV52811383; called by muse, mutect2, varscan2
- MICAL3 | c.4486C>T p.R1496W | Missense Mutation (SNP) | VAF 156/760 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as rs9617621; called by muse, varscan2
- MIEF2 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 147/717 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1303117428; called by muse, mutect2, varscan2
- MMP25 | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 214/534 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs941609555; called by muse, mutect2, varscan2
- MMS19 | c.2474T>C p.M825T | Missense Mutation (SNP) | VAF 74/291 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1486183888; called by muse, mutect2, varscan2
- MOB3C | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 94/657 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs112622804; called by muse, mutect2, varscan2
- MON1A | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 105/435 reads (24%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.935); catalogued as rs1370325523, COSV56560706; called by muse, mutect2, varscan2
- MOV10 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 32/508 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747208248, COSV53517225; called by muse, mutect2
- MRC2 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 93/470 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs987552256; called by muse, mutect2, varscan2
- MST1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 60/406 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs780890872, COSV56534070; called by muse, mutect2, varscan2
- MST1R | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 29/358 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs867261592, COSV56575125; called by muse, mutect2
- MTCL1 | c.2488C>T p.R830C (on ENST00000306329 / NM_001378206.1; = p.R470C on NM_015210.4) | Missense Mutation (SNP) | VAF 159/748 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as rs201898483; called by muse, mutect2, varscan2
- MUC16 | c.6762del p.S2255Pfs*6 | Frame Shift Del (DEL) | VAF 57/360 reads (16%) | catalogued as rs776993869, COSV67451814; called by mutect2, pindel, varscan2
- MUC2 | c.3785C>T p.P1262L | Missense Mutation (SNP) | VAF 127/533 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1273808979; called by muse, mutect2, varscan2
- MUC5B | c.15804del p.T5269Lfs*25 | Frame Shift Del (DEL) | VAF 128/538 reads (24%) | catalogued as rs1307335173; called by mutect2, varscan2
- MYBPC3 | c.2735G>A p.G912D | Missense Mutation (SNP) | VAF 113/406 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.627); catalogued as rs867959512; called by muse, mutect2, varscan2
- MYCBP2 | c.3893G>A p.R1298Q (on ENST00000357337; = p.R1336Q on NM_015057.5) | Missense Mutation (SNP) | VAF 38/503 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs776842585; called by muse, mutect2
- MYH3 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 84/493 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV56862507; called by muse, mutect2, varscan2
- MYH4 | c.5116G>A p.A1706T | Missense Mutation (SNP) | VAF 88/432 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs1251252157; called by muse, mutect2, varscan2
- MYH7B | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 121/667 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs568840401; called by muse, mutect2, varscan2
- MYH9 | c.4822G>A p.A1608T | Missense Mutation (SNP) | VAF 93/588 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV99337745; called by muse, mutect2, varscan2
- MYLK3 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 31/488 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776941985, COSV67362833, COSV67365893; called by muse, mutect2
- MYO10 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 78/371 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs1198750767, COSV72454862; called by muse, mutect2, varscan2
- MYO15A | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 134/807 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as rs1471937980; called by muse, mutect2, varscan2
- MYO15B | c.7673C>T p.A2558V | Missense Mutation (SNP) | VAF 145/626 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as rs750073819; called by muse, mutect2, varscan2
- MYO3A | c.4825C>T p.R1609C | Missense Mutation (SNP) | VAF 146/688 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99394310; called by muse, mutect2, varscan2
- MYOM3 | c.4165G>T p.E1389* | Nonsense Mutation (SNP) | VAF 94/564 reads (17%) | catalogued as COSV58393298; called by muse, mutect2, varscan2
- MYT1L | c.181del p.R61Efs*20 | Frame Shift Del (DEL) | VAF 52/301 reads (17%) | catalogued as rs1417217555; called by mutect2, pindel, varscan2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 69/300 reads (23%) | catalogued as rs763929397; called by mutect2, varscan2
- NACAD | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 140/582 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as rs577795802; called by muse, mutect2, varscan2
- NAGPA | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 135/550 reads (25%) | PolyPhen probably damaging (0.98); catalogued as rs377424631; called by muse, mutect2, varscan2
- NARF | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 85/467 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as rs757271058; called by muse, mutect2, varscan2
- NAV2 | c.3181C>T p.R1061W (on ENST00000396087 / NM_001244963.2; = p.R1038W on NM_145117.5) | Missense Mutation (SNP) | VAF 76/502 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759047624; called by muse, mutect2, varscan2
- NBEAL2 | c.6791G>A p.R2264H | Missense Mutation (SNP) | VAF 65/392 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs369069276; called by muse, mutect2, varscan2
- NBN | c.283del p.D95Mfs*14 | Frame Shift Del (DEL) | VAF 37/348 reads (11%) | catalogued as CM066927; called by pindel, varscan2
- NCAN | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 58/296 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53049941; called by muse, mutect2, varscan2
- NCAPG | c.2885C>T p.T962M | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs200488618, COSV52268646; called by muse, mutect2, varscan2
- NCOA6 | c.3968G>A p.R1323Q | Missense Mutation (SNP) | VAF 69/491 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1419410838; called by muse, mutect2, varscan2
- NCOR1 | c.5380C>T p.R1794* | Nonsense Mutation (SNP) | VAF 56/275 reads (20%) | catalogued as rs1567776756, COSV51980991; called by muse, mutect2, varscan2
- NDST3 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 61/299 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56621152; called by muse, mutect2, varscan2
- NEB | c.14494G>A p.V4832I | Missense Mutation (SNP) | VAF 84/363 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs368484176; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEK10 | c.1054T>G p.S352A | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as rs1273451458; called by muse, mutect2
- NELL2 | c.743T>C p.L248S | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs1359342690, COSV61576028; called by muse, mutect2, varscan2
- NEURL3 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 181/804 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.293); catalogued as rs1046494931; called by muse, mutect2, varscan2
- NEURL4 | c.1657G>A p.V553M | Missense Mutation (SNP) | VAF 26/499 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1172015572, COSV59756019; called by muse, mutect2
- NEUROD1 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 46/666 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as COSV54549174; called by muse, mutect2
- NF1 | c.5084G>A p.R1695Q (on ENST00000358273 / NM_001042492.3; = p.R1674Q on NM_000267.3) | Missense Mutation (SNP) | VAF 19/514 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs1555533367, COSV55986689; ClinVar: uncertain significance; called by muse, mutect2
- NFKBIL1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 186/830 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201771654; called by muse, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 72/246 reads (29%) | catalogued as rs145147241; called by mutect2, varscan2
- NKX1-2 | c.752dup p.S252Qfs*143 | Frame Shift Ins (INS) | VAF 91/616 reads (15%) | catalogued as rs1011006333; called by mutect2, pindel, varscan2
- NLGN1 | c.83C>A p.P28Q | Missense Mutation (SNP) | VAF 100/478 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.031); catalogued as COSV64346394; called by muse, mutect2, varscan2
- NLRC3 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 115/744 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV57087942; called by muse, mutect2, varscan2
- NLRP2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 123/532 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs1165462336, COSV54756823; called by muse, mutect2, varscan2
- NLRP6 | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 166/645 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762893596, COSV56460269; called by muse, mutect2, varscan2
- NLRP7 | c.1474G>A p.G492S | Missense Mutation (SNP) | VAF 29/1037 reads (3%) | SIFT tolerated (0.49); PolyPhen benign (0.292); catalogued as rs529348651, COSV60182791; called by muse, mutect2
- NOP53 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 79/877 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs1250736001; called by muse, mutect2
- NOS2 | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 90/464 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs767806769, COSV100569683; called by muse, mutect2, varscan2
- NOTCH2 | c.5111G>A p.R1704H | Missense Mutation (SNP) | VAF 81/384 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.139); catalogued as rs764895571, CM137595; called by muse, mutect2, varscan2
- NPW | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1446915232; called by muse, mutect2
- NRBP2 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 88/836 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs149352521, COSV59919079; called by muse, varscan2
- NRXN2 | c.4790G>A p.R1597H | Missense Mutation (SNP) | VAF 184/778 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); catalogued as COSV55451157; called by muse, varscan2
- NTNG2 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 178/793 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62368614; called by muse, mutect2, varscan2
- NUFIP1 | c.526del p.C176Vfs*27 | Frame Shift Del (DEL) | VAF 46/205 reads (22%) | catalogued as rs1566064574; called by mutect2, pindel, varscan2
- NUP205 | c.3039dup p.P1014Tfs*48 | Frame Shift Ins (INS) | VAF 50/267 reads (19%) | catalogued as rs1459298648; called by mutect2, pindel, varscan2
- NUP88 | c.70T>G p.F24V | Missense Mutation (SNP) | VAF 110/601 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs771131496; called by muse, mutect2, varscan2
- NWD1 | c.3114A>T p.Q1038H | Missense Mutation (SNP) | VAF 84/533 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV60344271; called by muse, mutect2, varscan2
- NXF3 | c.1592C>T p.S531L | Missense Mutation (SNP) | VAF 101/478 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs758955368, COSV67702707, COSV67705135; called by muse, mutect2, varscan2
- OBSCN | c.2356G>A p.A786T | Missense Mutation (SNP) | VAF 73/471 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs369543744; called by muse, mutect2, varscan2
- OGFRL1 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 36/184 reads (20%) | catalogued as rs140294148; called by muse, mutect2, varscan2
- OLFM1 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 60/365 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.074); catalogued as rs1437974589; called by muse, varscan2
- OLFML1 | c.302A>G p.Y101C | Missense Mutation (SNP) | VAF 83/324 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61404255; called by muse, mutect2, varscan2
- OLIG3 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 64/881 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as rs1489856221; called by muse, mutect2
- OPN1MW | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 177/808 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs782051833; called by muse, mutect2, varscan2
- OPN3 | c.1089dup p.V364Sfs*15 | Frame Shift Ins (INS) | VAF 46/504 reads (9%) | catalogued as rs1415832848; called by mutect2, pindel
- OR10Z1 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 83/442 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV63526904; called by muse, mutect2, varscan2
- OR2G6 | c.911T>C p.L304P | Missense Mutation (SNP) | VAF 83/320 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs115003693; called by muse, mutect2, varscan2
- OR2T33 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 171/1126 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.187); catalogued as rs777287203, COSV100531481, COSV58816166; called by muse, mutect2, varscan2
- OR4A15 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 84/504 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs374555766, COSV59036488; called by muse, mutect2, varscan2
- OR5AR1 | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 83/345 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV57253925; called by muse, mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 64/229 reads (28%) | catalogued as rs746200712; called by mutect2, varscan2
- OR7A5 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 72/353 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as rs572102214, COSV59235884; called by muse, mutect2, varscan2
- OR8D2 | c.756del p.F252Lfs*4 | Frame Shift Del (DEL) | VAF 58/332 reads (17%) | catalogued as rs1238695261, COSV62488687; called by mutect2, varscan2
- OR8J3 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1244601435, COSV56882235; called by muse, mutect2, varscan2
- OSBPL7 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 31/835 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201239698; called by muse, mutect2
- OSGEP | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1305108351, COSV52834321; called by muse, mutect2, varscan2
- OTOGL | c.4337C>A p.P1446H (on ENST00000547103; = p.P1437H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/312 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as COSV72006359; called by muse, mutect2, varscan2
- OTUD6B | c.527_528del p.V176Gfs*9 | Frame Shift Del (DEL) | VAF 60/539 reads (11%) | catalogued as rs1472577530; called by pindel, varscan2
- OTUD7B | c.161del p.P54Hfs*98 | Frame Shift Del (DEL) | VAF 86/485 reads (18%) | catalogued as COSV64916305; called by mutect2, pindel, varscan2
- P2RX1 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 94/373 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs1454866122; called by muse, mutect2, varscan2
- PA2G4 | c.1115del p.K372Rfs*16 | Frame Shift Del (DEL) | VAF 50/263 reads (19%) | catalogued as rs746871475; called by mutect2, varscan2
- PABPC5 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 139/601 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); catalogued as COSV100442529; called by muse, mutect2, varscan2
- PACS1 | c.2446T>C p.Y816H | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs1022637248; called by muse, mutect2
- PALM2AKAP2 | c.88C>T p.R30* (on ENST00000374531 / NM_001037293.2; = p.R28* on NM_007203.5) | Nonsense Mutation (SNP) | VAF 33/205 reads (16%) | catalogued as rs957556066, COSV57116702; called by muse, mutect2, varscan2
- PAX3 | c.1175T>C p.V392A | Missense Mutation (SNP) | VAF 58/336 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.701); catalogued as rs906415673; called by muse, mutect2, varscan2
- PBRM1 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV56264876; called by muse, mutect2, varscan2
- PCDH1 | c.3081dup p.K1028Qfs*49 | Frame Shift Ins (INS) | VAF 114/583 reads (20%) | catalogued as rs776686446; called by mutect2, varscan2
- PCDHA5 | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 143/658 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); catalogued as COSV100972172; called by muse, mutect2, varscan2
- PCDHB14 | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 22/347 reads (6%) | catalogued as COSV53386784, COSV53389653; called by muse, mutect2
- PCDHB2 | c.2341G>A p.A781T | Missense Mutation (SNP) | VAF 40/330 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50634804; called by muse, mutect2, varscan2
- PCDHB5 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 124/490 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.673); catalogued as rs782202851, COSV50668388; called by muse, varscan2
- PCDHB7 | c.1958C>T p.S653L | Missense Mutation (SNP) | VAF 215/2019 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1358732711, COSV50791293, COSV99176156; called by muse, mutect2, varscan2
- PCDHGA1 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 171/1035 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65295131; called by muse, mutect2, varscan2
- PCDHGA5 | c.1444G>A p.G482S | Missense Mutation (SNP) | VAF 88/534 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.206); catalogued as rs1353944459; called by muse, varscan2
- PCDHGA9 | c.1217C>T p.T406M | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs199556803, COSV53916555; called by muse, mutect2, varscan2
- PCDHGB1 | c.97T>C p.Y33H | Missense Mutation (SNP) | VAF 143/569 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs562243473; called by muse, mutect2, varscan2
- PCDHGB6 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 34/488 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53942289; called by muse, mutect2
- PCK1 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 77/429 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.071); catalogued as rs766102409, COSV100101106, COSV60127483; called by muse, mutect2, varscan2
- PCLO | c.10378A>G p.R3460G | Missense Mutation (SNP) | VAF 71/367 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.189); catalogued as rs1488927067; called by muse, varscan2
- PCLO | c.10364G>A p.R3455Q | Missense Mutation (SNP) | VAF 95/376 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as rs756859068, COSV61634372; called by muse, varscan2
- PCNT | c.2581G>A p.A861T | Missense Mutation (SNP) | VAF 106/523 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as rs377283848, COSV64027964; called by muse, mutect2, varscan2
- PCNT | c.7681C>T p.R2561C | Missense Mutation (SNP) | VAF 45/437 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs751345838; called by muse, mutect2, varscan2
- PCNT | c.7682G>A p.R2561H | Missense Mutation (SNP) | VAF 45/430 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs761765918, COSV64028563; called by muse, mutect2, varscan2
- PDE1B | c.1565del p.P522Hfs*25 | Frame Shift Del (DEL) | VAF 109/404 reads (27%) | catalogued as rs780236743; called by mutect2, varscan2
- PDE3B | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 48/636 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV56380404; called by muse, mutect2
- PDE3B | c.2947C>T p.Q983* | Nonsense Mutation (SNP) | VAF 74/371 reads (20%) | catalogued as COSV56380030; called by muse, mutect2, varscan2
- PDE4A | c.1862G>A p.R621H (on ENST00000380702 / NM_001111307.2; = p.R382H on NM_006202.3) | Missense Mutation (SNP) | VAF 119/543 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs373223236; called by muse, mutect2, varscan2
- PDE7A | c.1102C>T p.R368W (on ENST00000401827 / NM_001242318.3; = p.R342W on NM_002603.4) | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1392346825; called by muse, mutect2, varscan2
- PDLIM7 | c.901T>C p.Y301H | Missense Mutation (SNP) | VAF 88/618 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV62883798; called by muse, mutect2, varscan2
- PDS5A | c.3074G>A p.R1025H | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs937477858; called by muse, mutect2, varscan2
- PDZD7 | c.2220del p.V741Wfs*12 | Frame Shift Del (DEL) | VAF 134/538 reads (25%) | catalogued as rs1211492964; called by pindel, varscan2
- PDZRN3 | c.2144A>G p.Y715C | Missense Mutation (SNP) | VAF 103/536 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV55193916; called by muse, mutect2, varscan2
- PDZRN4 | c.395del p.G132Afs*96 | Frame Shift Del (DEL) | VAF 67/361 reads (19%) | catalogued as rs1203008747; called by mutect2, pindel, varscan2
- PECR | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 88/312 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs767429439, COSV54736136; called by muse, mutect2, varscan2
- PEX11G | c.41A>G p.Y14C | Missense Mutation (SNP) | VAF 151/561 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs773073586; called by muse, mutect2, varscan2
- PFKP | c.2130del p.K710Nfs*13 | Frame Shift Del (DEL) | VAF 58/245 reads (24%) | catalogued as rs760523015, COSV56535397; called by mutect2, pindel, varscan2
- PHACTR4 | c.151A>G p.K51E (on ENST00000373839 / NM_001350159.2; = p.K61E on NM_023923.4) | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs550399400, COSV65783432; called by mutect2, varscan2
- PHETA1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 160/801 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs572816860; called by muse, mutect2, varscan2
- PHF12 | c.686A>G p.N229S | Missense Mutation (SNP) | VAF 68/415 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.028); catalogued as rs144952764; called by muse, mutect2, varscan2
- PHKG1 | c.1132G>A p.V378M | Missense Mutation (SNP) | VAF 45/323 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs375841179; called by muse, mutect2, varscan2
- PHYKPL | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 116/437 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs145465078; called by muse, mutect2, varscan2
- PIF1 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 182/826 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1246734974; called by muse, mutect2, varscan2
- PIK3R6 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1402306026; called by muse, mutect2
- PIR | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 102/482 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs202040906; called by muse, mutect2, varscan2
- PISD | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 122/495 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs373015840, COSV100338712; called by muse, mutect2, varscan2
- PKHD1 | c.8140C>T p.R2714W | Missense Mutation (SNP) | VAF 49/297 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs754533251; called by muse, varscan2
- PLCXD3 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 83/415 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs757112105, COSV100125467, COSV60606218; called by muse, mutect2, varscan2
- PLEC | c.13130C>T p.A4377V (on ENST00000322810 / NM_201380.4; = p.A4267V on NM_000445.5) | Missense Mutation (SNP) | VAF 166/1035 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV59654440; called by muse, mutect2, varscan2
- PLEC | c.10849A>C p.S3617R (on ENST00000322810 / NM_201380.4; = p.S3507R on NM_000445.5) | Missense Mutation (SNP) | VAF 259/1533 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100508950; called by muse, mutect2, varscan2
- PLEC | c.9751G>A p.V3251I (on ENST00000322810 / NM_201380.4; = p.V3141I on NM_000445.5) | Missense Mutation (SNP) | VAF 146/944 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs768376288; called by muse, varscan2
- PLEKHH1 | c.3317C>T p.T1106M | Missense Mutation (SNP) | VAF 27/426 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs745537882, COSV100232651; called by muse, mutect2
- PLOD2 | c.1561T>C p.Y521H | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as CD149239; called by muse, mutect2, varscan2
- PLXNA2 | c.3980C>T p.P1327L | Missense Mutation (SNP) | VAF 80/379 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs995889959, COSV65445778; called by muse, mutect2, varscan2
- PLXNA3 | c.4568G>A p.R1523H | Missense Mutation (SNP) | VAF 104/605 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151166195, COSV100860113; called by muse, mutect2, varscan2
- POGK | c.833A>C p.D278A | Missense Mutation (SNP) | VAF 54/709 reads (8%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.463); catalogued as rs1216906900; called by muse, mutect2
- POLI | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149914424; called by muse, mutect2, varscan2
- POLRMT | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 66/898 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754938918, COSV52115548; called by muse, mutect2
- POTEB3 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 44/534 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1254735873; called by muse, mutect2
- POTEE | c.2422G>C p.A808P | Missense Mutation (SNP) | VAF 143/1170 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV58239062; called by muse, mutect2, varscan2
- POU4F2 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 234/945 reads (25%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as COSV99850705; called by muse, mutect2, varscan2
- PPARGC1A | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 57/265 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs143962880, COSV53524541; called by muse, mutect2, varscan2
- PPHLN1 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 49/319 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); catalogued as rs774470260, COSV56736461; called by muse, mutect2, varscan2
- PPP1R16A | c.1333del p.H445Tfs*15 | Frame Shift Del (DEL) | VAF 178/1268 reads (14%) | catalogued as rs777096925; called by mutect2, pindel, varscan2
- PPP1R3F | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 211/884 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.758); catalogued as rs1557121386, COSV50018253; called by muse, mutect2, varscan2
- PPP1R8 | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 36/518 reads (7%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.005); catalogued as COSV52580391; called by muse, mutect2
- PPP2R2B | c.31C>T p.R11* (on ENST00000394413 / NM_001271900.2; = p.I23= on NM_001271899.1) | Nonsense Mutation (SNP) | VAF 27/366 reads (7%) | catalogued as rs1442429822; called by muse, mutect2
- PPP6R2 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 102/470 reads (22%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.859); catalogued as rs150819801; called by muse, varscan2
- PRKACG | c.95del p.G32Efs*27 | Frame Shift Del (DEL) | VAF 91/541 reads (17%) | catalogued as COSV55240575; called by mutect2, pindel, varscan2
- PRKCD | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 78/327 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as rs376358631; called by muse, mutect2, varscan2
- PRLR | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs781305716, COSV99184419; called by muse, mutect2, varscan2
- PRMT3 | c.556dup p.M186Nfs*22 | Frame Shift Ins (INS) | VAF 58/265 reads (22%) | catalogued as rs759247233; called by mutect2, pindel, varscan2
- PRR12 | c.485G>C p.G162A (on ENST00000615927; = p.G983A on NM_020719.3) | Missense Mutation (SNP) | VAF 62/1062 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.04); catalogued as rs1309608700, COSV69817815; called by muse, mutect2
- PSMD1 | c.1426G>A p.G476S | Missense Mutation (SNP) | VAF 57/243 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58077802; called by muse, mutect2, varscan2
- PTEN | c.44G>T p.R15I | Missense Mutation (SNP) | VAF 72/292 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs398123324, COSV100910708, COSV64297317, COSV64299553; called by muse, mutect2, varscan2
- PTF1A | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 73/522 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64734936; called by muse, mutect2, varscan2
- PTGFRN | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 127/794 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289023140, COSV67798278; called by muse, mutect2, varscan2
- PTK2B | c.2959G>A p.A987T | Missense Mutation (SNP) | VAF 162/712 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs774754713, COSV53558784; called by muse, mutect2
- PTPN21 | c.2042G>T p.R681M | Missense Mutation (SNP) | VAF 185/730 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.429); catalogued as COSV60846532; called by muse, mutect2, varscan2
- PTPN21 | c.44A>G p.Y15C | Missense Mutation (SNP) | VAF 114/504 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1006681700; called by muse, mutect2, varscan2
- PTPRN | c.92del p.G31Afs*75 | Frame Shift Del (DEL) | VAF 81/364 reads (22%) | catalogued as rs1179811215; called by mutect2, pindel, varscan2
- PTPRU | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 164/741 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60523829; called by muse, mutect2, varscan2
- PUF60 | c.590del p.G197Afs*12 (on ENST00000526683 / NM_001362896.2; = p.G180Afs*12 on NM_014281.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 113/885 reads (13%) | catalogued as COSV100252546; called by mutect2, pindel, varscan2
- PWWP2B | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 128/827 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs1315448512; called by muse, mutect2, varscan2
- RAD54L | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 104/489 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs141019694; called by muse, mutect2, varscan2
- RAD54L2 | c.1613C>A p.P538H | Missense Mutation (SNP) | VAF 118/512 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99620580; called by muse, mutect2, varscan2
- RALGAPA1 | c.3142A>G p.M1048V | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs1169020604; called by muse, mutect2
- RBFOX2 | c.733G>A p.V245M (on ENST00000438146 / NM_001349995.2; = p.V175M on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/488 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as rs779812829; called by muse, mutect2, varscan2
- RBM10 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 135/669 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.129); catalogued as COSV61313793; called by muse, mutect2, varscan2
- RBM24 | c.611C>T p.A204V (on ENST00000379052 / NM_001143942.2; = p.A159V on NM_153020.2) | Missense Mutation (SNP) | VAF 46/592 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs1418843247; called by muse, mutect2
- RBSN | c.2301_2302del p.N768Sfs*16 | Frame Shift Del (DEL) | VAF 54/367 reads (15%) | catalogued as rs1245463059; called by pindel, varscan2
- RGL4 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 90/411 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs764399514, COSV51943965; called by muse, mutect2, varscan2
- RGS20 | c.451del p.H151Ifs*3 | Frame Shift Del (DEL) | VAF 121/948 reads (13%) | catalogued as rs35570213; called by mutect2, pindel, varscan2
- RGS6 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 44/707 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs368125974, COSV59563439; called by muse, mutect2
- RIMS2 | c.1875del p.G626Efs*3 (on ENST00000666250 / NM_001348490.2; = p.G434Efs*3 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 39/286 reads (14%) | catalogued as rs1282720554; called by mutect2, pindel, varscan2
- RIPOR1 | c.2903G>A p.R968Q (on ENST00000379312 / NM_001193522.2; = p.R964Q on NM_024519.4) | Missense Mutation (SNP) | VAF 133/496 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.548); catalogued as rs137895953; called by muse, mutect2, varscan2
- RMDN3 | c.1156del p.T386Lfs*22 | Frame Shift Del (DEL) | VAF 60/300 reads (20%) | catalogued as rs745408248; called by mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 60/214 reads (28%) | catalogued as rs757038390; called by mutect2, varscan2
- RNFT2 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 135/608 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs374059009; called by muse, mutect2, varscan2
- ROBO3 | c.3230C>T p.P1077L | Missense Mutation (SNP) | VAF 128/543 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1326139558; called by muse, mutect2, varscan2
- ROCK2 | c.412del p.W138Gfs*31 | Frame Shift Del (DEL) | VAF 48/329 reads (15%) | catalogued as rs755738345; called by mutect2, pindel, varscan2
- RORB | c.1196T>A p.I399N (on ENST00000396204 / NM_001365023.1; = p.I388N on NM_006914.4) | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV65337487; called by muse, mutect2
- RP1 | c.3737C>T p.A1246V | Missense Mutation (SNP) | VAF 97/572 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV55120637; called by muse, mutect2, varscan2
- RPL7A | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as rs748690917, COSV59300251; called by muse, mutect2, varscan2
- RRP36 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs760969484, COSV99763582; called by muse, mutect2, varscan2
- RTKN2 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 90/412 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs757266154, COSV59523152; called by muse, mutect2, varscan2
- RTN4R | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 101/656 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as rs751619193; called by muse, varscan2
- RUNX1 | c.613C>T p.R205W (on ENST00000344691 / NM_001001890.3; = p.R232W on NM_001754.5) | Missense Mutation (SNP) | VAF 143/608 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55867793; called by muse, mutect2, varscan2
- RYR2 | c.13002G>A p.M4334I | Missense Mutation (SNP) | VAF 24/593 reads (4%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.977); catalogued as COSV63687284, COSV63702121; called by muse, mutect2
- RYR3 | c.12574G>A p.V4192M (on ENST00000389232; = p.V4193M on NM_001036.6) | Missense Mutation (SNP) | VAF 75/428 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.031); catalogued as rs747458680, COSV66787095; called by muse, mutect2, varscan2
- SAMD4A | c.2059G>A p.V687M | Missense Mutation (SNP) | VAF 90/413 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.474); catalogued as rs571117167; called by muse, mutect2, varscan2
- SASH1 | c.3177del p.W1060Gfs*16 | Frame Shift Del (DEL) | VAF 120/833 reads (14%) | catalogued as rs761606832; called by mutect2, pindel, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 36/136 reads (26%) | catalogued as rs763290832; called by mutect2, varscan2
- SBK2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 166/687 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs115705351; called by muse, mutect2, varscan2
- SBK2 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 183/856 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.11); catalogued as rs752125711, COSV100705253, COSV60014854; called by muse, mutect2, varscan2
- SCART1 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 39/478 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.16); catalogued as rs776623123; called by muse, mutect2
- SCLT1 | c.1620del p.A541Pfs*3 | Frame Shift Del (DEL) | VAF 56/212 reads (26%) | catalogued as rs760494753; called by mutect2, varscan2
- SCN5A | c.5753A>G p.Q1918R (on ENST00000333535 / NM_198056.3; = p.Q1917R on NM_000335.5) | Missense Mutation (SNP) | VAF 52/712 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs878855295; ClinVar: uncertain significance; called by muse, mutect2
- SCRIB | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 52/1137 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1220253695; called by muse, mutect2
- SCRT1 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 81/510 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as rs1186676918; called by muse, mutect2, varscan2
- SDAD1 | c.824del p.K275Rfs*15 | Frame Shift Del (DEL) | VAF 30/200 reads (15%) | catalogued as rs763181092; called by mutect2, pindel, varscan2
- SDC2 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 65/619 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368635468; called by muse, mutect2
- SDK1 | c.4073G>A p.R1358H | Missense Mutation (SNP) | VAF 144/652 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1405867017; called by muse, mutect2, varscan2
- SEC16A | c.1689del p.F563Lfs*9 | Frame Shift Del (DEL) | VAF 146/625 reads (23%) | catalogued as COSV99255876; called by mutect2, pindel, varscan2
- SEC63 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.958); catalogued as rs765447143, COSV64601708; ClinVar: uncertain significance; called by muse, varscan2
- SEMA4F | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 97/518 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as rs371410540, COSV100336138; called by muse, mutect2, varscan2
- SEMA5B | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 73/542 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs982779433; called by muse, mutect2, varscan2
- SENP7 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); catalogued as COSV58619574; called by muse, mutect2
- SERINC1 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs1454177544; called by muse, mutect2
- SERPINC1 | c.1055T>C p.M352T | Missense Mutation (SNP) | VAF 130/584 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as CM044940; called by muse, mutect2, varscan2
- SETX | c.3932G>A p.R1311H | Missense Mutation (SNP) | VAF 84/342 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767094849, COSV99809732; called by muse, mutect2, varscan2
- SGSH | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 148/628 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as rs780969693, COSV100413452; called by muse, mutect2, varscan2
- SGSM2 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 44/688 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs754318308; called by muse, mutect2
- SH3RF3 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 117/585 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs1367340326, COSV58687796; called by muse, mutect2, varscan2
- SHISA7 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 62/942 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.184); catalogued as rs1295534946; called by muse, mutect2
- SHOC1 | c.2147del p.K716Sfs*16 | Frame Shift Del (DEL) | VAF 82/345 reads (24%) | catalogued as COSV59503990; called by mutect2, pindel, varscan2
- SHOX | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 121/604 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM021150, CM023452, COSV61861857, COSV61862377; called by muse, mutect2, varscan2
- SHPRH | c.1371del p.G458Efs*26 | Frame Shift Del (DEL) | VAF 40/242 reads (17%) | catalogued as rs774210627; called by mutect2, varscan2
- SHROOM2 | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 208/877 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs771710705, COSV101098185; called by muse, mutect2, varscan2
- SIAH3 | c.236A>G p.H79R | Missense Mutation (SNP) | VAF 157/648 reads (24%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs1566085741; called by mutect2, varscan2
- SIGLEC1 | c.2465G>A p.R822H | Missense Mutation (SNP) | VAF 154/741 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs777553761, COSV52460450; called by muse, mutect2, varscan2
- SIMC1 | c.2302G>A p.E768K (on ENST00000443967 / NM_001308196.1; = p.E353K on NM_198567.5) | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs769706590, COSV57904810; called by muse, mutect2, varscan2
- SIRT6 | c.738+1G>A p.X246_splice | Splice Site (SNP) | VAF 130/511 reads (25%) | catalogued as rs202077007; called by muse, mutect2, varscan2
- SLC12A9 | c.305del p.G102Afs*6 | Frame Shift Del (DEL) | VAF 80/461 reads (17%) | catalogued as rs766637822; called by mutect2, pindel, varscan2
- SLC16A6 | c.294dup p.L99Afs*34 | Frame Shift Ins (INS) | VAF 94/484 reads (19%) | catalogued as rs782184620; called by mutect2, varscan2
- SLC24A2 | c.1592G>A p.S531N | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs573307561; called by muse, mutect2
- SLC2A4 | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 36/415 reads (9%) | catalogued as rs756669509; called by muse, mutect2
- SLC2A6 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 23/832 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs116078552; called by muse, mutect2
- SLC32A1 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 184/731 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.301); catalogued as rs968205956, COSV54146280, COSV99462168; called by muse, mutect2, varscan2
- SLC38A10 | c.3148C>T p.R1050W | Missense Mutation (SNP) | VAF 182/731 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750737602, COSV101043003; called by muse, mutect2, varscan2
- SLC4A2 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 108/527 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59658013; called by muse, mutect2, varscan2
- SLC6A12 | c.1194_1197del p.C399Wfs*5 | Frame Shift Del (DEL) | VAF 56/280 reads (20%) | catalogued as rs1398772985; called by mutect2, pindel, varscan2
- SLC6A3 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 127/481 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs138948519; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC7A4 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 154/643 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs372373397; called by muse, mutect2, varscan2
- SLC9C2 | c.2866C>T p.R956C | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs776106559, COSV62944078, COSV62948312; called by muse, mutect2, varscan2
- SLCO1C1 | c.1544del p.N515Ifs*23 | Frame Shift Del (DEL) | VAF 24/222 reads (11%) | catalogued as rs1248990770; called by mutect2, pindel
- SLCO5A1 | c.1729T>C p.Y577H | Missense Mutation (SNP) | VAF 86/523 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1563658466; called by muse, mutect2, varscan2
- SLITRK1 | c.1543C>A p.L515M | Missense Mutation (SNP) | VAF 99/478 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65674401, COSV65677478; called by muse, mutect2, varscan2
- SMAP1 | c.613del p.S205Vfs*15 (on ENST00000370455 / NM_001044305.3; = p.S178Vfs*15 on NM_021940.5) | Frame Shift Del (DEL) | VAF 31/287 reads (11%) | catalogued as rs766085867, COSV100391091; called by mutect2, pindel, varscan2
- SMARCA1 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779258095, COSV64410986; called by muse, mutect2, varscan2
- SMARCAD1 | c.1040del p.N347Mfs*24 | Frame Shift Del (DEL) | VAF 50/214 reads (23%) | catalogued as rs754697669; called by mutect2, varscan2
- SMCHD1 | c.2040del p.K680Nfs*3 | Frame Shift Del (DEL) | VAF 47/241 reads (20%) | catalogued as rs766211852; called by mutect2, pindel, varscan2
- SMPD1 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 159/612 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as rs373508268, COSV54968110; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMYD2 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs369877948; called by muse, mutect2, varscan2
- SOBP | c.2059C>T p.R687C | Missense Mutation (SNP) | VAF 55/405 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); catalogued as rs1277454682; called by muse, mutect2, varscan2
- SOGA1 | c.4244G>A p.R1415H | Missense Mutation (SNP) | VAF 51/704 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1032753440, COSV99415052; called by muse, mutect2
- SOS1 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs952307464; called by muse, mutect2, varscan2
- SOX30 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 28/516 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53936280; called by muse, mutect2
- SP7 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 112/748 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs756905984; called by muse, mutect2, varscan2
- SPART | c.1299G>A p.W433* | Nonsense Mutation (SNP) | VAF 44/228 reads (19%) | catalogued as COSV100768745; called by muse, mutect2, varscan2
- SPATA31E1 | c.3403A>G p.M1135V | Missense Mutation (SNP) | VAF 97/720 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370011827; called by muse, mutect2, varscan2
- SPATA5L1 | c.1578C>G p.F526L | Missense Mutation (SNP) | VAF 91/482 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99972953; called by muse, mutect2, varscan2
- SPDYE5 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 42/495 reads (8%) | catalogued as rs782820334; called by muse, mutect2
- SPECC1 | c.2729G>A p.R910H | Missense Mutation (SNP) | VAF 91/433 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs371442923; called by muse, mutect2, varscan2
- SPEG | c.8480C>A p.P2827H | Missense Mutation (SNP) | VAF 137/558 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV100404531; called by muse, mutect2, varscan2
- SPRY1 | c.319A>G p.R107G | Missense Mutation (SNP) | VAF 101/425 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1415724393; called by muse, mutect2, varscan2
- SPTBN1 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 112/602 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as rs993913630; called by muse, mutect2, varscan2
- SPTBN5 | c.5888G>A p.R1963H | Missense Mutation (SNP) | VAF 128/595 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.03); catalogued as rs756663149; called by muse, mutect2, varscan2
- SREK1IP1 | c.381del p.K129Nfs*29 | Frame Shift Del (DEL) | VAF 36/191 reads (19%) | catalogued as rs1470980144, COSV72486131; called by mutect2, pindel, varscan2
- SRPRA | c.1140G>A p.T380= | Splice Region (SNP) | VAF 73/330 reads (22%) | catalogued as rs200174931, COSV99702414; called by muse, mutect2, varscan2
- SRRT | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 102/632 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs766105030, COSV61452395; called by muse, varscan2
- SRSF4 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441731561, COSV65695639; called by muse, mutect2
- SSBP4 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 113/680 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as rs1015353916; called by muse, mutect2, varscan2
- SSTR5 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 131/874 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.075); catalogued as rs548054752, COSV53513301; called by muse, mutect2, varscan2
- ST18 | c.1552A>G p.I518V | Missense Mutation (SNP) | VAF 82/515 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs745820953, COSV99390958; called by muse, mutect2, varscan2
- ST6GAL2 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 42/699 reads (6%) | PolyPhen possibly damaging (0.514); catalogued as COSV64527764; called by muse, mutect2
- ST6GALNAC1 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 135/552 reads (24%) | PolyPhen probably damaging (0.941); catalogued as rs904834191; called by muse, mutect2, varscan2
- STAG1 | c.2544G>T p.M848I | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52612362; called by muse, mutect2, varscan2
- STAT4 | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 36/471 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.762); catalogued as rs755096256; called by muse, mutect2
- STAT5A | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 113/514 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1231666878; called by muse, mutect2, varscan2
- STC1 | c.600C>A p.D200E | Missense Mutation (SNP) | VAF 121/636 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV51689006; called by muse, mutect2, varscan2
- STIMATE | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 70/306 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs1204760383; called by muse, mutect2, varscan2
- STRN4 | c.851G>A p.S284N | Missense Mutation (SNP) | VAF 39/577 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs759601307; called by muse, mutect2
- STYXL2 | c.3152G>A p.R1051K | Missense Mutation (SNP) | VAF 32/650 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54802823; called by muse, mutect2
- SUV39H1 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 144/571 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1463984801; called by muse, mutect2, varscan2
- SYCP1 | c.2376del p.D793Tfs*65 | Frame Shift Del (DEL) | VAF 22/87 reads (25%) | catalogued as rs745637836; called by mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 49/119 reads (41%) | catalogued as rs570102997; called by mutect2, varscan2
- SYNE1 | c.10276A>G p.T3426A (on ENST00000367255 / NM_182961.4; = p.T3433A on NM_033071.3) | Missense Mutation (SNP) | VAF 86/351 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1423503302; called by muse, mutect2, varscan2
- SYNE2 | c.16024G>A p.G5342S | Missense Mutation (SNP) | VAF 60/271 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs34541826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE2 | c.19160C>T p.P6387L | Missense Mutation (SNP) | VAF 53/727 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs756722459; called by muse, mutect2
- TACR3 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 126/533 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.067); catalogued as rs200656206, COSV100510892; called by muse, mutect2, varscan2
- TAGLN2 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 42/664 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as rs374231815; called by muse, mutect2
- TANGO2 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 136/514 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs780152948, COSV59293153; called by muse, mutect2, varscan2
- TBC1D30 | c.2384C>T p.T795M (on ENST00000542120; = p.T632M on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/679 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.556); catalogued as rs1052729003; called by muse, mutect2, varscan2
- TBC1D8 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 116/429 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs199891498; called by muse, mutect2, varscan2
- TBCD | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 154/749 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs774219082; called by muse, mutect2, varscan2
- TBX2 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 206/914 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV53598673; called by muse, mutect2, varscan2
- TCF3 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 146/648 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1374875669, COSV99514649; called by muse, mutect2, varscan2
- TDRD5 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 45/315 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as rs745715035; called by muse, mutect2, varscan2
- TECTA | c.5840G>A p.R1947H | Missense Mutation (SNP) | VAF 104/410 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs202104412; called by muse, mutect2, varscan2
- TEDDM1 | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 82/442 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs1165903794; called by muse, mutect2, varscan2
- TENM2 | c.2264G>A p.R755H (on ENST00000518659 / NM_001122679.2; = p.R523H on NM_001080428.3) | Missense Mutation (SNP) | VAF 93/545 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs201674742, COSV69126648; called by muse, mutect2, varscan2
- TEP1 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 52/586 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.056); catalogued as rs202114016; called by muse, mutect2
- TET2 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 81/392 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.451); catalogued as rs150072691; called by muse, mutect2, varscan2
- TG | c.7900C>T p.L2634F | Missense Mutation (SNP) | VAF 44/743 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55087166; called by muse, mutect2
- TLE1 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 50/400 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs771899498; called by muse, mutect2, varscan2
- TMEM121 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 208/916 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV66796358; called by muse, mutect2, varscan2
- TMEM140 | c.43A>G p.M15V | Missense Mutation (SNP) | VAF 110/463 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs754734068; called by muse, mutect2, varscan2
- TMEM161A | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 105/450 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749796937; called by muse, mutect2, varscan2
- TMEM179 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 129/778 reads (17%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs1233720011; called by muse, mutect2, varscan2
- TMEM184A | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 160/608 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as rs748661397; called by muse, mutect2, varscan2
- TMEM200C | c.1089del p.R364Afs*13 | Frame Shift Del (DEL) | VAF 130/964 reads (13%) | catalogued as rs1237699327; called by mutect2, pindel, varscan2
- TMEM235 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 100/458 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as rs555201618; called by muse, mutect2, varscan2
- TMEM259 | c.942+1G>A p.X314_splice | Splice Site (SNP) | VAF 105/396 reads (27%) | catalogued as rs1188609279; called by muse, mutect2, varscan2
- TMEM43 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 46/422 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs201138253; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TMEM88B | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 179/716 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs954373895; called by muse, mutect2, varscan2
- TMEM94 | c.657del p.F220Sfs*31 | Frame Shift Del (DEL) | VAF 94/640 reads (15%) | catalogued as rs753764149; called by mutect2, pindel, varscan2
- TMPRSS15 | c.499A>G p.K167E | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.162); catalogued as rs1345487539; called by muse, mutect2, varscan2
1,567 further variants in this file (955 protein-altering or splice-affecting, 527 silent, 85 other) are not listed here.
